Gene-level copy-number profile of tumor specimen TCGA-09-2051-01A from TCGA case TCGA-09-2051, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 42.8 years (15,650 days).
Specimen TCGA-09-2051-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.3c96b2d3-8778-4c9c-8bf9-dc7559292fa9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-09-2051-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c7518eb2-5ca6-4831-b04b-9e730ab87ef8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,147; copy number 2: 21,968; copy number 3: 16,576; copy number 4: 11,582; copy number 5: 5,073; copy number 6: 1,984; copy number 7: 91; copy number 8: 325; copy number 9: 38; copy number 10: 3; copy number 12: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-09-2051-01A-01D-0704-01): tumor purity 0.74, ploidy 3.04, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,483 genes in 33 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–20,718,017, 673 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:143,343,180–198,322,420, 1,446 genes, copy number 5–6 (broad region; genes not listed).
- chr1:224,107,282–248,919,946, 620 genes, copy number 5–6 (broad region; genes not listed).
- chr2:30,910,467–35,471,841, 65 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:121,040,610–121,310,412, 5 genes, copy number 5: Y_RNA, AC067960.1, AC079988.1, TFCP2L1, RPS17P7.
- chr3:13,316,235–15,601,852, 55 genes, copy number 5: NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2, LINC00620, WNT7A, VN1R20P, FGD5P1, TPRXL, AC090004.2, VN1R21P, CHCHD4, TMEM43, AC090004.1, XPC-AS1, XPC, LSM3, AC093496.1, LINC01267, RNA5SP124, SLC6A6, GRIP2, RNU6-905P, RHBDF1P1, AC090952.2, AC090952.1, CCDC174, C3orf20, AC090957.1, AC087591.1, LINC02011, FGD5, FGD5-AS1, NR2C2, MRPS25, RBSN, AC090954.1, RPS3AP53, COL6A4P1, CAPN7, SH3BP5-AS1, SH3BP5, RNU6-454P, HMGN2P7, METTL6, EAF1, RNU6-1024P, EAF1-AS1, COLQ, MIR4270, AC027129.1, RN7SL110P, HACL1.
- chr3:103,159,960–103,540,487, 4 genes, copy number 7: RNU1-43P, NDUFA4P2, MIR548AB, AC046144.1.
- chr3:150,408,335–198,222,513, 843 genes, copy number 5–10 (broad region; genes not listed).
- chr5:33,162,179–45,895,970, 207 genes, copy number 5–9 (broad region; genes not listed).
- chr7:30,284,597–43,566,001, 223 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr7:114,922,359–115,833,373, 11 genes, copy number 5: MDFIC, LINC01393, LINC01392, RAC1P6, Y_RNA, POLR2DP2, SNORA25B, AC092590.1, AC093714.1, AC093714.2, Y_RNA.
- chr8:41,426,655–47,202,897, 105 genes, copy number 5 (broad region; genes not listed).
- chr8:100,572,889–145,066,685, 692 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:4,633,027–4,769,895, 7 genes, copy number 6: AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1.
- chr9:6,195,934–6,727,438, 18 genes, copy number 5: GTF3AP1, IL33, AL360221.1, SELENOTP1, TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57, AL162411.1, RN7SL123P, RPS3AP54, RNF2P1, RPL35AP20, LINC02851, AL354707.1.
- chr9:6,734,598–6,835,577, 3 genes, copy number 5: PRELID3BP11, SNRPEP2, ACTG1P14.
- chr9:7,597,823–7,598,377, 1 gene, copy number 5: PPIAP33.
- chr9:7,914,514–36,304,924, 455 genes, copy number 5 (broad region; genes not listed).
- chr10:1,957,589–14,462,142, 222 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:24,952,350–25,161,236, 1 gene, copy number 5 (within-gene range 4–5): AL512598.2.
- chr10:24,981,979–36,626,138, 207 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:494,512–2,001,470, 93 genes, copy number 5 (broad region; genes not listed).
- chr11:2,129,121–2,129,964, 1 gene, copy number 5: AC132217.1.
- chr11:20,043,846–30,850,559, 110 genes, copy number 5–6 (broad region; genes not listed).
- chr11:31,812,307–39,261,213, 116 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:9,594,551–9,895,833, 17 genes, copy number 7: KLRB1, RNU6-700P, GOT2P3, AC010186.4, AC010186.1, AC010186.2, AC010186.3, CLEC2D, NPM1P7, LINC02390, CLECL1, CD69, GCNAP1, KLRF1, CLEC2B, AC091814.1, KLRF2.
- chr12:18,080,869–31,073,847, 207 genes, copy number 6–12 (within-gene range 4–12) (broad region; genes not listed).
- chr12:31,076,867–31,077,016, 1 gene, copy number 6: SNORA75.
- chr15:96,354,237–101,933,350, 134 genes, copy number 5–6 (broad region; genes not listed).
- chr19:29,489,775–30,228,715, 20 genes, copy number 6 (within-gene range 4–6): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1.
- chr19:33,067,175–36,246,257, 169 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr20:31,844,303–49,188,367, 483 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr20:54,178,414–64,313,132, 269 genes, copy number 6–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,551. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
